Surgical pathology report (de-identified scan), TCGA case TCGA-24-1464, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1464-01A (Primary Tumor).

[page 1 of 5]
Patient Name: 1

DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient Name:

Address:

Gender: F

DOB:

Physician(s):

Service:

Location:

MRN:

Hospital

Patient Type

Accession #:

Taken

Received:

Reported:

Other Related Clinical Data:

DIAGNOSIS: OVARY, LEFT, SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED ADENOCARCINOMA (SEE COMMENT)

OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- PERITUBAL SIMPLE CYST

SPECIMEN LABELED "HERNIA SAC AND NODULE," EXCISION
- POORLY DIFFERENTIATED ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- DISORDERED PROLIFERATIVE ENDOMETRIUM
- ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY
- EXTENSIVE INVOLVEMENT OF LYMPHATIC SPACES BY METASTATIC ADENOCARCINOMA

LYMPH NODE, RIGHT COMMON, EXCISION
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

[page 2 of 5]
Patient Name:

DOB:

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING TWO OF TWO LYMPH NODES (2/2)

LYMPH NODES, RIGHT OBTURATOR, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING TWO OF TWO LYMPH NODES (2/2)

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING ONE OF TWO LYMPH NODES (1/2)

LYMPH NODES, LEFT OBTURATOR, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING TWO OF SIX LYMPH NODES (2/6)

LYMPH NODES, RIGHT PERI-AORTIC, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING TWO OF TWO LYMPH NODES (2/2)

LYMPH NODE, LEFT PERI-AORTIC, EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING ONE LYMPH NODE (1/1)

OMENTUM, OMENTECTOMY
- NO CARCINOMA IDENTIFIED

APPENDIX, APPENDECTOMY
- METASTATIC ADENOCARCINOMA INVOLVING PERIAPPENDICEAL SOFT TISSUE
- MUOCOCELE

SMALL INTESTINE, MESENTERIC MASS, EXCISION
- METASTATIC ADENOCARCINOMA (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation: #2, section of umbilical hernia "nodule", resection - pick up only

FS1 - Left ovary mass
- "Adenocarcinoma" by

Microscopic Description and Comment: Histologic sections from the left ovarian mass show a poorly differentiated adenocarcinoma. The tumor is present predominantly in sheets of cells with large vesicular nuclei and occasional tumor giant cells. In some areas the tumor is present in thin single file cords invading a desmoplastic stroma. Other areas show rhabdoid features with perinuclear eosinophilic cytoplasm. A significant minority of the tumor forms well-defined endometrioid-type glands. These glands appear to be present in an adenofibromatous stroma. Metastatic adenocarcinoma extensively involves the lymphatics of the myometrium but no serosal implants are present. The endometrium has been entirely submitted and exhibits a disordered proliferative pattern but no carcinoma is identified. The right ovary (entirely submitted) and both fallopian tubes are free of carcinoma. Metastatic adenocarcinoma is present in periappendiceal soft tissue. The appendix also contains a focal mucocele but no carcinoma involving epithelium is present. Metastatic adenocarcinoma is present in 2 of 2 right external iliac lymph nodes, 2 of 2 right obturator lymph nodes, 1 of 2 left external iliac lymph nodes, 2 of 6 left obturator lymph nodes, 2 of 2 right peri-aortic lymph nodes, and 1 of 1 left peri-aortic lymph nodes. One right common iliac lymph node is free of carcinoma. Poorly differentiated adenocarcinoma is present in

[page 3 of 5]
Patient Name:

DOB:

the specimen labeled "umbilical hernia and nodule. The single submitted section from the specimen labeled "small bowel mesenteric mass" appears to represent near total replacement of a large lymph node. The omentum is free of carcinoma.

Given the somewhat unusual morphologic features immunostains were performed. The tumor is negative for gross cystic disease fluid protein an antibody that stains approximately 60 to 80% of breast carcinomas. The tumor is focally positive for S-100 and is strongly positive for CA-125 in the better differentiated endometrioid areas. Although the morphologic features and tumor distribution are somewhat unusual, in the absence of another primary tumor these features are consistent with a mullerian (ovarian) primary. has reviewed selected slides and concurs with this interpretation. (D:

History: The patient is a year old woman with an abdominal mass. Operative procedure: Hysterectomy, removal of abdominal mass, multiple node samplings.

Specimen(s) Received:

A: MASS, LEFT OVARY
B: UMBILICAL HERNIA \T\ NODULE
C: UTERUS CERVIX RIGHT OVARY RIGHT TUBE
D: RIGHT COMMON NODES
E: RIGHT EXTERNAL NODES
F: RIGHT OBTURATOR NODES
G: OMENTUM
H: EXTERNAL NODES, LEFT
I: LEFT OBTURATOR NODES
J: RIGHT PERI AORTIC NODES
K: LEFT PERI AORTIC NODES
L: APPENDIX
M: SMALL BOWEL MESSENTARY MASS

Gross Description Thirteen formalin-filled containers are received, each labeled with the patient's name. The first container is labeled "uterus, left ovary and tube." It contains a white cassette labeled FS1. It contains a section of white-tan mass, measuring 1.5 x 1.8 x 0.2 cm. Labeled A1 - FS. Also present in the container is a large irregularly shaped mass, measuring 18 x 15 x 14 cm and weighing 1100 grams after fixation. The surface is covered by a glistening membrane, is irregular, nodular and partially hemorrhagic. No tumor is evident outside the capsule. There is a thin walled cyst present, measuring 4 x 3.5 x 6 cm. A fragment of the left fallopian tube is present on the surface of the mass, measuring 4.5 cm in length and 0.3 cm in diameter. The fimbriae are not evident. On sectioning, the tumor mass is mostly solid, firm, tan-brown with areas of hemorrhage and necrosis. Only minute cystic areas are present except the previously described cyst. No normal ovarian parenchyma is identified. No uterus is present in the container. Labeled: A2 - left fallopian tube; A3 to A11 - sections of the tumor. Jar 5.

The second container is labeled "section of umbilical hernia and nodule." It contains an elliptical excision of skin including the umbilicus, measuring 4.5 x 1.2 cm on the skin surface and 5 cm from skin surface to deep resection margin. The skin surface is unremarkable. The deep resection margin is inked black. Sections show a tan-pink, circumscribed nodule, measuring 3 x 2 x 1.5 cm. The mass does not reach the inked margin. Labeled B1. Jar 1.

The third container is labeled "uterus, cervix, right ovary, right tube." It contains the uterus with attached right fallopian tube and ovary, weighing 86 grams and measuring 5

[page 4 of 5]
Patient Name.

DOB:

cm from cornu to cornu, 9.8 cm from cornu to cervix, and 3.0 cm anterior-posteriorly. The cervix measures 3.5 x 2 cm, scant ectocervix is present. The endocervix measures 3.8 cm in length and 1.5 cm in diameter, and is unremarkable. The endometrial cavity measures 5.5 x 3.0 cm. The endometrium is 0.1 cm thick, slightly nodular and hemorrhagic. There is a 0.8 x 0.5 cm endometrial polyp present in the left cornu. The myometrium is 1.5 cm thick and unremarkable. The serosa is unremarkable. The right fallopian tube measures 5 cm in length and 0.3 cm in diameter. The attached right ovary measures 2.8 x 1.8 x 0.6 cm. Sections are unremarkable. Labeled: C1 - anterior cervix; C2 - anterior endomyometrium; C3 - anterior endomyometrium with endometrial polyp; C4 - posterior cervix; C5 - posterior endomyometrium; C6 - right fallopian tube; C7 - right ovary, C8 - remainder of the right ovary, EM9-EM20 - remainder of endometrium. Jar 2.

The fourth container is labeled "R common node." It contains two fragments of fibrofatty tissue, measuring 1 x 0.8 x 0.3, and 1.8 x 0.5 x 0.5 cm. No lymph node is grossly identified in the fat. Labeled D1. Jar 0.

The fifth container is labeled "R external node." It contains multiple fragments of fibrofatty tissue, measuring 5.5 x 3 x 1 cm in aggregate. Two lymph nodes are dissected from the fat, measuring 0.3 x 0.2 x 0.2 and 2 x 1.5 x 1 cm. The larger lymph node is grossly suspicious for metastasis. Labeled E1. Jar 1.

The sixth container is labeled "Rt obturator node." It contains several fragments of fibrofatty tissue, measuring 1.5 x 3 x 1.5 cm in aggregate. Two lymph nodes are dissected from the fat, measuring 3 x 0.5 x 0.5 and 2 x 1 x 1 cm. Labeled F1. Jar 1.

The seventh container is labeled "omentum." It contains the omentum, measuring 44 x 15 x 1.5 cm. It is yellow, soft and fatty. Sections show no identifiable lesion. Labeled G1 to G5. Jar 2.

The eighth container is labeled "L external node." It contains several fragments of fibrofatty tissue, measuring 4.5 x 3 x 1.5 cm in aggregate. Several lymph nodes are dissected from the fat. Labeled H1. Jar 1.

The ninth container is labeled "L obturator L node." It contains several fragments of fibrofatty tissue, measuring 4 x 2.5 x 2 cm in aggregate. Several lymph nodes are dissected from the fat, two of them show replacement of their parenchyma by white, firm tumor tissue. Labeled I1 and I2. Jar 1.

The tenth container is labeled "right periaortic node." It contains three fragments of soft tissue, measuring 1 x 0.2 x 0.2, 2 x 0.5 x 0.2, and 2.5 x 0.8 x 0.5. The smallest fragment contains a surgical staple. Several lymph nodes are dissected from the fat. Labeled J1. Jar 1.

The eleventh container is labeled "left periaortic node." It contains a single fragment of soft tissue with two surgical staples, measuring 1.5 x 1.5 x 0.5 cm. Sections show one lymph node. Labeled K1. Jar 1.

The twelfth container is labeled "appendix." It contains an appendix, measuring 6.5 x 0.5 x 0.5 cm. The serosa is unremarkable, except an attached lymph node at the tip. The wall measures 0.1 cm in thickness. The lumen is not identifiable. Labeled L1-L4. Jar 1.

The thirteenth container is labeled "small bowel mesenteric mass." It contains eight fragments of partially serosa-covered, tan-white, irregularly shaped nodules. They range in size from 1 to 4.5 cm in largest diameter. Sections show firm, tan-white, partially hemorrhagic and necrotic tumor. Labeled M1. Jar 1.

[page 5 of 5]
Patient Name:

DOB:

1

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is
PRESENT 2. The HISTOLOGIC DIAGNOSIS is: Adenocarcinoma

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Left ovary only
4. The FIGO GRADE of the tumor is: III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. Tumor IS NOT identified on the ovarian surface(s).
- 7 Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Invasion of pelvic soft tissue cannot be assessed
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is ABSENT.
13. The maximum dimension of tumor implants outside the true pelvis is 3.0 cm
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are PRESENT.
17. The total number of regional lymph nodes examined is: 16
18. The total number of metastatically-involved regional lymph nodes is: 10
- Extranodal extension by tumor metastases is ABSENT.

19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:
TNM Scheme FIGO Scheme Definition

T3c IIIc regional
lymph node metastases
THE REGIONAL LYMPH NODES are classified as: N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX 20. The FINAL AJCC/FIGO STAGE IS:
AJCC Scheme FIGO Scheme

x insufficient data to assign stage The pathologic stage assigned here should be regarded
as provisional, and may change after integration of clinical data not provided with this
specimen.

Source: NCI Genomic Data Commons file b84ff193-3791-4229-99e8-8d495973abb3 (TCGA-24-1464.242047B0-E0E3-4BA3-A0DF-95887392602E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).